Somatic mutation profile of tumor specimen C3L-03364-02 (aliquot CPT0284960006) from CPTAC case C3L-03364, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.3 years (19,844 days).
Specimen C3L-03364-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea4da79a-26a7-4a40-b8c7-1ac539dc0523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03364-31 (Blood Derived Normal), aliquot CPT0286900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5019feb-76d4-4902-a1ca-223726044992

The open-access MAF lists 312 somatic variants for this specimen: 197 protein-altering or splice-affecting, 105 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 179, Silent 105, Nonsense Mutation 7, Splice Region 6, Intron 6, Splice Site 4, 3'UTR 1, Frame Shift Del 1, 5'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 349/515 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB1 | c.2397+1G>A p.X799_splice | Splice Site (SNP) | VAF 64/263 reads (24%) | catalogued as COSV55945099; called by muse, mutect2, varscan2
- ABHD12B | c.661G>A p.G221R (on ENST00000337334 / NM_001206673.2; = p.G144R on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs1327562123; called by muse, mutect2, varscan2
- ABT1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs1561910494; called by muse, mutect2, varscan2
- ACY3 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 321/891 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761480551; called by muse, mutect2, varscan2
- ADAM19 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 126/417 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV57433555; called by muse, mutect2, varscan2
- ADPRHL1 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1012766222; called by muse, mutect2, varscan2
- AFDN | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV60049321; called by muse, mutect2, varscan2
- AGRN | c.5125G>A p.G1709R | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM094737; called by muse, mutect2, varscan2
- ALAS2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 128/432 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177147185; called by muse, mutect2, varscan2
- ATG9B | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs772234685; called by muse, mutect2, varscan2
- BAZ1A | c.2112G>A p.G704= | Splice Region (SNP) | VAF 57/165 reads (35%) | catalogued as rs1170746030; called by muse, mutect2, varscan2
- C19orf73 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 52/207 reads (25%) | catalogued as COSV55522516; called by muse, mutect2, varscan2
- C9orf50 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); catalogued as rs1328366351; called by muse, mutect2, varscan2
- CD38 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as rs1043356811; called by muse, mutect2, varscan2
- CENPF | c.3086G>A p.C1029Y | Missense Mutation (SNP) | VAF 74/344 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs775764747; called by muse, mutect2, varscan2
- CEP250 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 124/476 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs767867819; called by muse, mutect2, varscan2
- CHAT | c.385T>A p.S129T | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs756873370; called by muse, mutect2, varscan2
- COL6A6 | c.3509G>A p.R1170K | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs753977264, COSV62029614; called by muse, mutect2, varscan2
- CR1L | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 114/472 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1342301915; called by muse, mutect2, varscan2
- CXXC5 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs752725317; called by muse, mutect2, varscan2
- DDX11 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 96/650 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.089); catalogued as rs149773582, COSV99300618; called by muse, mutect2, varscan2
- DOK7 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 138/470 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as rs761289689; called by muse, mutect2, varscan2
- EFHC1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100931834; called by muse, mutect2, varscan2
- EML2 | c.999C>T p.V333= | Splice Region (SNP) | VAF 60/208 reads (29%) | catalogued as rs1019395440; called by muse, mutect2, varscan2
- EP300 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 76/825 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99607725; called by muse, mutect2
- EPHA7 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1465346253, COSV65168785; called by muse, mutect2, varscan2
- F2R | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as rs1051926439; called by muse, mutect2, varscan2
- F5 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1557916759; called by muse, mutect2, varscan2
- FGF4 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 142/2976 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs1382292721; called by muse, mutect2
- FTHL17 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 131/427 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs769677031; called by muse, mutect2, varscan2
- GALNT14 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as rs754388586; called by muse, mutect2, varscan2
- HECTD2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs1447834984, COSV53226046; called by muse, mutect2, varscan2
- HIVEP2 | c.2008G>A p.G670S | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs773860371; called by muse, mutect2, varscan2
- HNRNPA1 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV52939122; called by muse, mutect2, varscan2
- HTR6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53871632; called by muse, mutect2, varscan2
- IL17RD | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV56338124; called by muse, mutect2, varscan2
- KCTD18 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 152/494 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs201465092; called by muse, mutect2, varscan2
- KDM5A | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 94/331 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as rs546854883, COSV66995097; called by muse, mutect2, varscan2
- KDR | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs778028304; called by muse, mutect2, varscan2
- KIAA0319 | c.390G>A p.W130* | Nonsense Mutation (SNP) | VAF 98/420 reads (23%) | catalogued as COSV100985340, COSV65501894; called by muse, mutect2, varscan2
- KMT2C | c.6313G>A p.V2105M | Missense Mutation (SNP) | VAF 90/331 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100067472; called by muse, mutect2, varscan2
- LRRC43 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 111/449 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs746169489; called by muse, mutect2, varscan2
- LSM1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 88/290 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563275514; called by muse, mutect2, varscan2
- MAN1C1 | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182710634; called by muse, mutect2, varscan2
- MAP6 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 94/711 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs760776050; called by muse, mutect2, varscan2
- MUC22 | c.3241G>T p.G1081C | Missense Mutation (SNP) | VAF 198/607 reads (33%) | SIFT tolerated (0.05); catalogued as COSV101643249; called by mutect2, varscan2
- MXRA5 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 142/480 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs769720962; called by muse, mutect2, varscan2
- NHLRC4 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 32/631 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99215861; called by muse, mutect2
- NMUR2 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99677032; called by muse, mutect2, varscan2
- OR10G4 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs765624489, COSV57978402, COSV57978779; called by muse, mutect2, varscan2
- OR5D14 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV100162553; called by muse, mutect2, varscan2
- OSBPL5 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); catalogued as COSV55144169; called by muse, mutect2, varscan2
- OXA1L | c.977C>T p.P326L (on ENST00000285848; = p.P266L on NM_005015.5) | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329571819; called by muse, mutect2, varscan2
- PCDHB4 | c.1898A>G p.D633G | Missense Mutation (SNP) | VAF 154/529 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1334663235; called by muse, mutect2, varscan2
- PLAAT5 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 139/279 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57137178; called by muse, mutect2, varscan2
- PON2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1041182781; called by muse, mutect2, varscan2
- PPRC1 | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1220963452; called by muse, mutect2, varscan2
- PRKAA2 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 86/329 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV64806158; called by muse, mutect2, varscan2
- PRKG1 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs868326823; called by muse, mutect2, varscan2
- PROSER1 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.382); catalogued as rs1454945596; called by muse, mutect2, varscan2
- PRR35 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 178/489 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV53465280; called by muse, mutect2, varscan2
- PTGR2 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 80/294 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.528); catalogued as rs994801953; called by muse, mutect2, varscan2
- RCSD1 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 143/642 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762687259; called by muse, mutect2, varscan2
- RPS6KL1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 176/486 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1038605364, COSV63580747; called by muse, mutect2, varscan2
- RRM2 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 91/310 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs749005405; called by muse, mutect2, varscan2
- RYR3 | c.8936G>A p.R2979Q (on ENST00000389232; = p.R2980Q on NM_001036.6) | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs200346049, COSV66785492; called by muse, mutect2, varscan2
- SELENOO | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 80/575 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1287785763; called by muse, mutect2, varscan2
- SETX | c.3770C>T p.S1257L | Missense Mutation (SNP) | VAF 98/213 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs773081186; called by muse, mutect2, varscan2
- SLC7A4 | c.1623G>A p.Q541= | Splice Region (SNP) | VAF 76/186 reads (41%) | catalogued as COSV100298657; called by muse, mutect2, varscan2
- SLF1 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs926455341; called by muse, mutect2, varscan2
- SLK | c.3604G>A p.V1202I | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1023059773; called by muse, mutect2, varscan2
- SVEP1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237989; called by muse, mutect2, varscan2
- TENM4 | c.3632G>A p.R1211H | Missense Mutation (SNP) | VAF 125/680 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as rs555336301, COSV99578977; called by muse, mutect2, varscan2
- TTC17 | c.1499G>A p.W500* | Nonsense Mutation (SNP) | VAF 73/216 reads (34%) | catalogued as COSV50007753; called by muse, mutect2, varscan2
- VCX3A | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 68/814 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs1434315447; called by muse, mutect2
- VENTX | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.912); catalogued as rs755770897, COSV100383984, COSV58084468; called by muse, mutect2, varscan2
- VPS13A | c.142C>T p.L48= | Splice Region (SNP) | VAF 43/112 reads (38%) | catalogued as rs1450505752; called by muse, mutect2, varscan2
- VSX2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 145/443 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV56218482; called by muse, mutect2, varscan2
- WDR6 | c.99G>A p.A33= | Splice Region (SNP) | VAF 84/233 reads (36%) | catalogued as COSV100637657; called by muse, mutect2, varscan2
- XRN1 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV99377136; called by muse, mutect2, varscan2
- ZNF266 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV104419113; called by muse, varscan2
- ZNF574 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs1437354365; called by muse, mutect2, varscan2
- ABTB2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFF4 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP10 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 151/507 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- AOC2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 145/472 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AOC2 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 113/403 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AREG | c.358A>C p.T120P | Missense Mutation (SNP) | VAF 97/326 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ARRDC2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASB8 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATAD3A | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG3 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ATP5MF | c.21T>G p.C7W | Missense Mutation (SNP) | VAF 125/270 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAT2 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 95/298 reads (32%) | called by muse, mutect2, varscan2
- C8G | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- CASP7 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC157 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 169/490 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCPG1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CEACAM7 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CEP295 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CFP | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 147/474 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- COL28A1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CPNE1 | c.826G>A p.D276N (on ENST00000352393; = p.D281N on NM_003915.5) | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CSTF2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- DAPK1 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF15 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DCLRE1C | c.1930G>A p.D644N (on ENST00000378278 / NM_001350965.2; = p.D529N on NM_022487.4) | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DGKI | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 74/633 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DNM1L | c.1784C>T p.T595I (on ENST00000549701 / NM_012062.5; = p.T558I on NM_005690.4) | Missense Mutation (SNP) | VAF 99/312 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 110/429 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTHD1 | c.712G>A p.G238S (on ENST00000456874; = p.G73S on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF5B | c.3331G>A p.G1111R | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ELAPOR2 | c.1118C>T p.P373L (on ENST00000450689 / NM_001142749.3; = p.P206L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ELOVL4 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EP300 | c.6356C>T p.P2119L | Missense Mutation (SNP) | VAF 132/1206 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FAM126B | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM89A | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 113/524 reads (22%) | called by muse, mutect2, varscan2
- FAT3 | c.4816G>A p.E1606K | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FNDC7 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 127/502 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNIP2 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXN1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.18147G>A p.M6049I | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- GAREM2 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- GPATCH8 | c.3224G>A p.G1075E | Missense Mutation (SNP) | VAF 148/442 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GRK6 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GRK7 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 131/461 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GRM3 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- GRM5 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 120/612 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCFC1 | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHEX | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 111/368 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- HYAL1 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 126/381 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.5312G>A p.G1771E | Missense Mutation (SNP) | VAF 134/2091 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGFBP2 | c.814-1G>A p.X272_splice | Splice Site (SNP) | VAF 57/223 reads (26%) | called by muse, mutect2, varscan2
- IQSEC2 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 169/489 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- IRX5 | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 114/396 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ISL2 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 101/324 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IZUMO1R | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 120/399 reads (30%) | called by muse, mutect2, varscan2
- KIAA2013 | c.1887G>A p.K629= | Splice Region (SNP) | VAF 140/494 reads (28%) | called by muse, mutect2, varscan2
- LAMC2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LEMD2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIMD1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRP8 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 103/396 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LYG2 | c.622A>T p.K208* | Nonsense Mutation (SNP) | VAF 54/196 reads (28%) | called by mutect2, varscan2
- MACF1 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 94/325 reads (29%) | called by muse, mutect2, varscan2
- MAST2 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MCM6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); called by muse, varscan2
- MLLT6 | c.1798C>T p.L600F | Missense Mutation (SNP) | VAF 139/545 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTHFR | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MTMR14 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYCBP2 | c.3368C>T p.S1123F (on ENST00000357337; = p.S1161F on NM_015057.5) | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NAA15 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NABP2 | c.59T>C p.I20T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NRG1 | c.1681G>A p.E561K (on ENST00000405005 / NM_013964.5; = p.E566K on NM_013956.5) | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2A2 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PCDH15 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCF11 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 120/1204 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- PDZD8 | c.2897C>T p.P966L | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHACTR3 | c.1329-1G>A p.X443_splice | Splice Site (SNP) | VAF 79/330 reads (24%) | called by muse, mutect2, varscan2
- PHKG1 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- PIKFYVE | c.282del p.K94Nfs*14 | Frame Shift Del (DEL) | VAF 77/317 reads (24%) | called by mutect2, pindel, varscan2
- PLCL2 | c.2906G>A p.G969E (on ENST00000615277 / NM_001144382.2; = p.G843E on NM_015184.5) | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PMEPA1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 164/703 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSG7 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 114/377 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM19 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RMC1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 80/255 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ROS1 | c.6487C>T p.P2163S | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3A3 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SGIP1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC26A11 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 128/461 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC39A5 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 99/395 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A3 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 50/910 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SMARCC2 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC1B | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SPTAN1 | c.5134-1G>A p.X1712_splice | Splice Site (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- TCAF1 | c.2522G>A p.G841D | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- THOC5 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TLR7 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TPCN1 | c.698T>G p.M233R | Missense Mutation (SNP) | VAF 112/404 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- TPR | c.3907G>A p.D1303N | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TPTE2 | c.893T>G p.V298G (on ENST00000400230 / NM_199254.2; = p.V221G on NM_130785.3) | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TTN | c.26042G>A p.C8681Y (on ENST00000591111; = p.C7754Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/345 reads (32%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBA7 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 110/319 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- UBXN11 | c.641G>A p.G214D (on ENST00000374221 / NM_183008.2; = p.G181D on NM_145345.2) | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- USP20 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 157/344 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP43 | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- WNK1 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- WNK2 | c.4880G>A p.G1627E (on ENST00000297954 / NM_001282394.1; = p.G1590E on NM_006648.3) | Missense Mutation (SNP) | VAF 134/318 reads (42%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.946); called by muse, varscan2
- ZFP3 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF148 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF266 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF431 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- ZNF469 | c.7211A>G p.Q2404R (on ENST00000437464; = p.Q2432R on NM_001367624.2) | Missense Mutation (SNP) | VAF 121/431 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ZNF518A | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF776 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 111/448 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- AC015802.6 | c.390C>T p.I130= | Silent (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- ACBD6 | c.396G>A p.K132= | Silent (SNP) | VAF 67/319 reads (21%) | called by muse, mutect2, varscan2
- ADAM11 | c.1923G>A p.A641= | Silent (SNP) | VAF 93/332 reads (28%) | catalogued as rs1186095089; called by muse, mutect2, varscan2
- ANK2 | c.5757C>T p.S1919= | Silent (SNP) | VAF 115/422 reads (27%) | catalogued as rs543514702, COSV52191748; called by muse, mutect2, varscan2
- ANO1 | c.702G>A p.L234= | Silent (SNP) | VAF 90/1308 reads (7%) | called by muse, mutect2
- ANXA6 | c.1641C>T p.F547= | Silent (SNP) | VAF 54/226 reads (24%) | called by muse, mutect2, varscan2
- APPBP2 | c.1102C>T p.L368= | Silent (SNP) | VAF 82/246 reads (33%) | called by muse, mutect2, varscan2
- ARFGAP3 | c.366T>C p.S122= | Silent (SNP) | VAF 62/1056 reads (6%) | catalogued as rs1423271579; called by muse, mutect2
- C10orf71 | c.4140T>A p.S1380= | Silent (SNP) | VAF 127/405 reads (31%) | called by muse, mutect2, varscan2
- C17orf80 | c.18C>T p.P6= | Silent (SNP) | VAF 57/199 reads (29%) | catalogued as COSV52147687; called by muse, mutect2, varscan2
- C1orf68 | c.549G>A p.L183= | Silent (SNP) | VAF 118/497 reads (24%) | called by muse, mutect2, varscan2
- CCNL1 | c.51G>A p.S17= | Silent (SNP) | VAF 116/332 reads (35%) | called by muse, mutect2, varscan2
- CDCA3 | c.270G>A p.V90= | Silent (SNP) | VAF 90/332 reads (27%) | called by muse, varscan2
- CFAP47 | c.6261C>T p.L2087= | Silent (SNP) | VAF 82/261 reads (31%) | called by muse, mutect2, varscan2
- CHAC2 | c.114C>T p.D38= | Silent (SNP) | VAF 93/288 reads (32%) | called by muse, mutect2, varscan2
- CITED2 | c.738C>T p.L246= | Silent (SNP) | VAF 49/320 reads (15%) | catalogued as rs201713364; called by muse, mutect2, varscan2
- CORO7 | c.2334C>T p.P778= | Silent (SNP) | VAF 114/379 reads (30%) | catalogued as rs770938661; called by muse, mutect2, varscan2
- CRTC3 | c.327G>A p.R109= | Silent (SNP) | VAF 100/373 reads (27%) | called by muse, mutect2, varscan2
- CRYBG2 | c.735G>A p.G245= | Silent (SNP) | VAF 102/380 reads (27%) | catalogued as rs764223582; called by muse, mutect2, varscan2
- DIDO1 | c.4413C>T p.S1471= | Silent (SNP) | VAF 136/611 reads (22%) | catalogued as rs1417075666, COSV56619517; called by muse, mutect2, varscan2
- EHD2 | c.339C>T p.A113= | Silent (SNP) | VAF 110/370 reads (30%) | called by muse, mutect2, varscan2
- EIF4H | c.522G>A p.R174= | Silent (SNP) | VAF 118/449 reads (26%) | called by muse, mutect2, varscan2
- EPC2 | c.558G>A p.R186= | Silent (SNP) | VAF 97/361 reads (27%) | catalogued as rs367545690; called by muse, mutect2, varscan2
- EWSR1 | c.1617G>A p.E539= | Silent (SNP) | VAF 85/276 reads (31%) | catalogued as rs1569125400; called by muse, mutect2, varscan2
- FAM117B | c.522C>T p.V174= | Silent (SNP) | VAF 104/336 reads (31%) | called by muse, varscan2
- FASN | c.150G>A p.R50= | Silent (SNP) | VAF 108/258 reads (42%) | called by muse, mutect2, varscan2
- FER1L6 | c.4476C>T p.P1492= | Silent (SNP) | VAF 133/409 reads (33%) | catalogued as rs752074909; called by muse, mutect2, varscan2
- FKBP9 | c.42C>T p.L14= | Silent (SNP) | VAF 92/367 reads (25%) | called by muse, mutect2, varscan2
- FSHR | c.1317G>A p.G439= | Silent (SNP) | VAF 131/423 reads (31%) | catalogued as rs773201730, COSV58619709; called by muse, mutect2, varscan2
- GNL1 | c.690C>T p.A230= | Silent (SNP) | VAF 129/451 reads (29%) | catalogued as rs1381041502; called by muse, mutect2, varscan2
- GPR21 | c.27G>A p.Q9= | Silent (SNP) | VAF 95/225 reads (42%) | called by muse, mutect2, varscan2
- GPX2 | c.396C>T p.S132= | Silent (SNP) | VAF 116/384 reads (30%) | called by muse, mutect2, varscan2
- GREB1 | c.2502G>A p.E834= | Silent (SNP) | VAF 95/300 reads (32%) | called by muse, mutect2, varscan2
- HEATR1 | c.300C>T p.H100= | Silent (SNP) | VAF 96/392 reads (24%) | called by muse, mutect2, varscan2
- HOMER3 | c.84C>T p.I28= | Silent (SNP) | VAF 144/431 reads (33%) | catalogued as COSV55359019; called by muse, mutect2, varscan2
- HOXC12 | c.771G>A p.Q257= | Silent (SNP) | VAF 105/399 reads (26%) | called by muse, mutect2, varscan2
- INTS3 | c.3087G>A p.R1029= | Silent (SNP) | VAF 112/497 reads (23%) | called by muse, mutect2, varscan2
- IRX4 | c.1425G>A p.G475= | Silent (SNP) | VAF 123/623 reads (20%) | called by muse, mutect2, varscan2
- KDM2B | c.132G>A p.P44= | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as rs1018112726; called by muse, mutect2, varscan2
- KDM4A | c.714C>T p.L238= | Silent (SNP) | VAF 95/319 reads (30%) | called by muse, mutect2, varscan2
- KIAA1549L | c.1077G>A p.V359= (on ENST00000321505; = p.V656= on NM_012194.3) | Silent (SNP) | VAF 119/374 reads (32%) | catalogued as rs765224714; called by muse, mutect2, varscan2
- KRT38 | c.477G>A p.E159= | Silent (SNP) | VAF 96/297 reads (32%) | catalogued as COSV55845657; called by muse, mutect2, varscan2
- KRT40 | c.768G>A p.R256= | Silent (SNP) | VAF 131/507 reads (26%) | called by muse, mutect2, varscan2
- KRT82 | c.525C>T p.A175= | Silent (SNP) | VAF 122/403 reads (30%) | catalogued as rs979476767; called by muse, mutect2, varscan2
- LAMC2 | c.3030G>A p.G1010= | Silent (SNP) | VAF 102/456 reads (22%) | catalogued as rs1272007731; called by muse, mutect2, varscan2
- LDLRAD2 | c.384C>T p.S128= | Silent (SNP) | VAF 164/547 reads (30%) | called by muse, mutect2
- LILRA6 | c.225G>A p.L75= | Silent (SNP) | VAF 162/537 reads (30%) | catalogued as rs748295379; called by muse, mutect2, varscan2
- LRFN3 | c.321G>A p.R107= | Silent (SNP) | VAF 127/431 reads (29%) | called by muse, mutect2, varscan2
- LRP10 | c.1371C>T p.V457= | Silent (SNP) | VAF 114/256 reads (45%) | called by muse, mutect2, varscan2
- LRRC41 | c.1029C>T p.H343= | Silent (SNP) | VAF 135/446 reads (30%) | catalogued as rs1413014642, COSV58439223; called by muse, mutect2, varscan2
- LRRC7 | c.2496C>T p.L832= (on ENST00000651989 / NM_001370785.2; = p.L799= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 114/385 reads (30%) | catalogued as COSV50527278; called by muse, mutect2, varscan2
- LRRC71 | c.1023C>T p.S341= | Silent (SNP) | VAF 99/431 reads (23%) | called by muse, mutect2, varscan2
- MAP3K14 | c.2112G>A p.E704= | Silent (SNP) | VAF 131/479 reads (27%) | catalogued as rs1567986569, COSV60925174; called by muse, mutect2, varscan2
- MED30 | c.324C>T p.P108= | Silent (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- MIP | c.84G>T p.L28= | Silent (SNP) | VAF 122/395 reads (31%) | catalogued as rs368415438; called by muse, mutect2, varscan2
- MRPL21 | c.246G>A p.K82= | Silent (SNP) | VAF 102/1060 reads (10%) | called by muse, mutect2
- MYH14 | c.4971G>A p.K1657= | Silent (SNP) | VAF 129/427 reads (30%) | catalogued as rs1287461412, COSV99222154; called by muse, mutect2, varscan2
- MYH7B | c.1110G>A p.G370= | Silent (SNP) | VAF 93/391 reads (24%) | called by muse, mutect2, varscan2
- NCL | c.264G>A p.K88= | Silent (SNP) | VAF 106/275 reads (39%) | called by muse, mutect2, varscan2
- NFIC | c.705C>T p.S235= | Silent (SNP) | VAF 79/307 reads (26%) | called by muse, mutect2, varscan2
- NIPBL | c.4116G>A p.R1372= | Silent (SNP) | VAF 40/234 reads (17%) | catalogued as rs1282996701; called by muse, mutect2, varscan2
- NOVA2 | c.1344C>T p.F448= | Silent (SNP) | VAF 138/407 reads (34%) | called by muse, mutect2, varscan2
- NXPH4 | c.672G>A p.G224= | Silent (SNP) | VAF 119/452 reads (26%) | catalogued as rs1336834943; called by muse, mutect2, varscan2
- OR5T2 | c.786G>A p.L262= | Silent (SNP) | VAF 107/387 reads (28%) | called by muse, mutect2, varscan2
- OR8D2 | c.675C>T p.I225= | Silent (SNP) | VAF 109/296 reads (37%) | catalogued as COSV100659025, COSV62488568; called by muse, mutect2, varscan2
- OXSM | c.1020G>A p.E340= | Silent (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1590C>T p.D530= (on ENST00000259318 / NM_001136562.3; = p.D761= on NM_007203.5) | Silent (SNP) | VAF 118/268 reads (44%) | called by muse, mutect2, varscan2
- PAX3 | c.1297C>T p.L433= | Silent (SNP) | VAF 127/558 reads (23%) | catalogued as COSV60586077; called by muse, mutect2, varscan2
- PCDH8 | c.3178C>T p.L1060= | Silent (SNP) | VAF 83/308 reads (27%) | called by muse, mutect2, varscan2
- PEX5 | c.243C>T p.T81= | Silent (SNP) | VAF 105/372 reads (28%) | called by muse, mutect2, varscan2
- POLE | c.6147C>T p.T2049= | Silent (SNP) | VAF 69/234 reads (29%) | called by muse, mutect2, varscan2
- POLR1A | c.747G>A p.Q249= | Silent (SNP) | VAF 112/288 reads (39%) | called by muse, mutect2, varscan2
- PRRC2B | c.5658C>T p.S1886= | Silent (SNP) | VAF 111/264 reads (42%) | catalogued as rs371121586; called by muse, mutect2, varscan2
- PSMD6 | c.600C>T p.L200= | Silent (SNP) | VAF 76/296 reads (26%) | catalogued as COSV55760358; called by muse, mutect2, varscan2
- PTCH2 | c.1936C>T p.L646= | Silent (SNP) | VAF 123/408 reads (30%) | called by muse, mutect2, varscan2
- RERE | c.463C>T p.L155= | Silent (SNP) | VAF 87/262 reads (33%) | called by muse, mutect2, varscan2
- RTN1 | c.720C>T p.D240= | Silent (SNP) | VAF 131/415 reads (32%) | catalogued as rs770052003; called by muse, mutect2, varscan2
- RUNX1 | c.186G>A p.L62= (on ENST00000344691 / NM_001001890.3; = p.L89= on NM_001754.5) | Silent (SNP) | VAF 145/470 reads (31%) | called by muse, mutect2, varscan2
- RYR3 | c.8157C>T p.P2719= (on ENST00000389232; = p.P2720= on NM_001036.6) | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as rs1227963148; called by muse, mutect2, varscan2
- SCAMP2 | c.156C>T p.T52= | Silent (SNP) | VAF 118/376 reads (31%) | catalogued as rs751408106; called by muse, mutect2
- SENP5 | c.1608C>T p.D536= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV60206367; called by muse, mutect2, varscan2
- SH3BP4 | c.198T>C p.Y66= | Silent (SNP) | VAF 115/287 reads (40%) | called by muse, mutect2, varscan2
- SIRPB1 | c.744C>T p.A248= | Silent (SNP) | VAF 95/201 reads (47%) | called by muse, mutect2, varscan2
- SLC12A7 | c.462C>T p.F154= | Silent (SNP) | VAF 100/3116 reads (3%) | called by muse, mutect2
- SND1 | c.2478C>T p.C826= | Silent (SNP) | VAF 103/416 reads (25%) | catalogued as rs750224581; called by muse, mutect2, varscan2
- SOX3 | c.1332C>G p.T444= | Silent (SNP) | VAF 86/365 reads (24%) | called by muse, mutect2, varscan2
- SREBF2 | c.2097C>T p.N699= | Silent (SNP) | VAF 124/2304 reads (5%) | catalogued as rs1420543576; called by muse, mutect2
- SSC5D | c.1419C>T p.P473= | Silent (SNP) | VAF 138/438 reads (32%) | called by muse, mutect2, varscan2
- STK17B | c.363G>T p.L121= | Silent (SNP) | VAF 59/243 reads (24%) | called by mutect2, varscan2
- TBC1D22A | c.414C>T p.L138= | Silent (SNP) | VAF 95/379 reads (25%) | catalogued as rs771625208; called by muse, mutect2, varscan2
- TESK1 | c.1692G>A p.E564= | Silent (SNP) | VAF 138/311 reads (44%) | catalogued as COSV99427522; called by muse, mutect2, varscan2
- TET3 | c.3258G>A p.G1086= | Silent (SNP) | VAF 80/310 reads (26%) | catalogued as rs1465858391; called by muse, mutect2, varscan2
- TIPARP | c.1056G>A p.R352= | Silent (SNP) | VAF 84/241 reads (35%) | called by muse, mutect2, varscan2
- TMBIM6 | c.451C>T p.L151= | Silent (SNP) | VAF 71/286 reads (25%) | called by muse, mutect2, varscan2
- TPP2 | c.1422A>T p.T474= | Silent (SNP) | VAF 69/228 reads (30%) | called by muse, mutect2, varscan2
- TRIM4 | c.1497G>A p.R499= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- TRIOBP | c.147C>T p.P49= | Silent (SNP) | VAF 134/408 reads (33%) | catalogued as COSV100730845; called by muse, mutect2, varscan2
- TXNDC11 | c.1206G>A p.L402= (on ENST00000356957 / NM_001303447.2; = p.L375= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 71/272 reads (26%) | called by muse, mutect2, varscan2
- URI1 | c.1575G>A p.K525= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as rs771039160; called by muse, mutect2, varscan2
- USP38 | c.2356C>T p.L786= | Silent (SNP) | VAF 93/290 reads (32%) | called by muse, mutect2, varscan2
- XPC | c.1950G>A p.K650= | Silent (SNP) | VAF 107/359 reads (30%) | called by muse, mutect2, varscan2
- ZBTB20 | c.1062G>A p.E354= (on ENST00000474710 / NM_001164342.2; = p.E281= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 111/425 reads (26%) | called by muse, mutect2, varscan2
- ZNF112 | c.1920G>A p.E640= (on ENST00000337401 / NM_001083335.2; = p.E634= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 108/382 reads (28%) | called by muse, mutect2, varscan2
- ZNF227 | c.1233G>A p.E411= | Silent (SNP) | VAF 92/298 reads (31%) | called by muse, mutect2, varscan2
- ZNF575 | c.682C>T p.L228= | Silent (SNP) | VAF 80/326 reads (25%) | called by muse, mutect2, varscan2
- ABCC6 | c.219+44G>A | Intron (SNP) | VAF 113/412 reads (27%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850637 C>T | 3'Flank (SNP) | VAF 45/160 reads (28%) | called by muse, mutect2, varscan2
- CAST | c.-59G>A | 5'UTR (SNP) | VAF 100/229 reads (44%) | called by muse, mutect2, varscan2
- CNOT3 | c.2037+69G>A | Intron (SNP) | VAF 99/401 reads (25%) | called by muse, mutect2, varscan2
- GALNS | c.120+465C>T | Intron (SNP) | VAF 88/324 reads (27%) | called by muse, mutect2, varscan2
- KYAT3 | c.*154A>G | 3'UTR (SNP) | VAF 30/332 reads (9%) | called by muse, mutect2
- MOSMO | chr16:22007648 G>A | 5'Flank (SNP) | VAF 74/267 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.2653+2292C>T | Intron (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2
- PDCD2 | c.876+215C>T | Intron (SNP) | VAF 69/270 reads (26%) | catalogued as rs926948041; called by muse, mutect2, varscan2
- RPGR | c.2520+680G>A | Intron (SNP) | VAF 78/242 reads (32%) | called by muse, mutect2, varscan2
